Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88L, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88L-01A (Primary Tumor).

[page 1 of 5]
Patient Results

Page 1 of 5

Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

1. Tissue next to right base prostate, resection: Fibrous tissue with benign prostatic glands present.
2. Tissue next to right base prostate, deeper, resection (2FS): Fibromuscular tissue. No tumor seen.
3. Right obturator, lymph node, resection: Lymph nodes (0/9). No tumor seen.
4. Left obturator lymph node, resection: Lymph nodes (0/9). No tumor seen.
5. Fat and lymph node over central prostate, resection: Fibroadipose tissue.
6. Prostate, resection:
- Adenocarcinoma, Gleason score 7 (3+4) involving 30% of the right and 15% of the left lobe.
- Perineural invasion is present
- No extra-capsular or seminal vesicle invasion present
- Margins of resection are tumor free

GCF TCD-3
Adenocarcinoma, acinar 8/40/13
path Adenocarcinoma NOS 8/40/13
Site Prostate NOS 6/1/9
7/10/13

PROSTATE GLAND: Radical Prostatectomy

Procedure
Radical prostatectomy

Prostate Size
Weight: 43.3 g
Size: 5.3 x 5.2 x 3.7cm

Lymph Node Sampling
Left/right obturator lymph node dissection

Histologic Type
Adenocarcinoma

Histologic Grade
Gleason Pattern

Primary Pattern
Grade 3

Secondary Pattern
Grade 4

Total Gleason Score: 7

Tumor Quantitation

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 5]
Patient Results

Page 2 of 5

Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:	Location:

Surgical Pathology	Final Results
---------------------------	----------------------

30% of the Right lobe
15% of the Left lobe

Extraprostatic Extension
Not identified

Seminal Vesicle Invasion
Not identified

Margins
Margins uninvolved by invasive carcinoma

Treatment Effect on Carcinoma
Not identified

Lymph-Vascular Invasion
Not identified

Perineural Invasion
Present

Pathologic Staging (pTNM)

TNM Descriptors
Primary Tumor (pT)
pT2c: Bilateral disease

Regional Lymph Nodes (pN)
pN0: No regional lymph node metastasis
18 nodes submitted or found

Number of Lymph Nodes Examined
Specify: 18

Number of Lymph Nodes Involved
Specify: 0

Distant Metastasis (pM)
Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: M with GI6/7 (3+4)
Specimen Taken For
Protocol: 01 - Yes Allocate Order to Protocol:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 3 of 5]
Gender: Male

Birth Date:

Admit Protocol:

Admit Protocol:

Admit Protocol:

Age:

Location:

Surgical PathologyFinal Results

PROCEDURE: Operative Findings: see op note Post-Operative Diagnosis:
see above

Pre-Operative Diagnosis: see above

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Tissue next to Right Base Prostate (1fs)
2. ROUTINE + 5FR.SLIDES, Tissue Next to Rt. Base Prostate Deeper(2fs)
3. OBTURATOR LYMPH NODE(S), Right
4. OBTURATOR LYMPH NODE(S), Left
5. FAT, And LN Over Anterior Prostate
6. PROSTATE

INTRAOPERATIVE CONSULTATION:

Received fresh from the Operating Room labeled with the patient's name, medical record number and further specified as follows:

1. "Tissue next to right base prostate", a red-tan soft tissue fragment measuring 0.7 x 0.5 x 0.3cm which is frozen in toto as 1FS.
- Diagnosis (1FS): Fibrous tissue with atypia glandular epithelium.
2. "Tissue next to right base prostate deeper", is a red-tan soft tissue fragment measuring 0.6 x 0.5 x 0.5 cm. It is frozen in toto as 2FS
- Diagnosis (2FS): Fibromuscular tissue.

The intraoperative consultation was performed by _____ and _____

GROSS DESCRIPTION: Received are 6 formalin-filled container labeled with the patient's name, medical record number, date of birth and further specified as:

1. "Tissue next to right base prostate" is the above-mentioned frozen section that is placed into a white cassette labeled _____
2. "Tissue next to right base prostate deeper" is the above-mentioned frozen section specimen that is transferred into a white cassette labeled _____
3. "Right obturator lymph node pocket" is a 6 x 4 x 2-cm aggregate of adipose-like tissue. There are multiple hard well-circumscribed nodules that are palpated and they are individually dissected with representative sections placed into white cassettes labeled 3A-3F.
4. "Left obturator lymph node pocket" is an aggregate of 3 cm of adipose-like tissue with lymphatic tissue. Well-circumscribed palpable nodules are felt and are individually dissected and placed into white cassettes labeled _____

[page 4 of 5]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol	Admit Protocol:	Age:
		Location:

Surgical PathologyFinal Results

5. "Fat and lymph node over central prostate" is an aggregate of 3 x 2 cm of adipose-like tissue that is submitted into white cassettes labeled

6. "Prostate" is a prostate specimen that consists of a prostatectomy weighing 43.3 grams with the following measurements: Left to right 5.3 cm, anterior to posterior 3.7 cm, apex to base 5.2 cm, left seminal vesicles: 5.6 x 1.7 x 0.8 cm, left vas deferens 4.8 x 0.8 cm, right seminal vesicles 4.5 x 4.6 x 1.4 cm, right vas deferens 5.7 cm in length and 0.7 cm in diameter. Additionally, there are 3 detached cauterized rubbery tissue fragments, ranging from 1.5 to 2.6 cm in greatest dimension and 3.6 x 3 x 1.2 cm in the aggregate which states is from the urinary bladder base of the prostate. There are multiple sutures on the right anterior and lateral aspect of the gland. The prostate is inked as follows: Urethra in yellow, anterior 1/3 in black, right posterior 2/3 in blue, and left posterior 2/3 in red. Gross photographs are taken. One cut is made revealing a tan soft tissue nodular cut surface and ill-defined tan-pink nodularity, 1.7 cm in greatest dimension in the right mid PZ. Approximately 0.5 x 0.5 x 0.3 cm of tissue from the right mid PZ nodularity and 0.6 x 0.5 x 0.3 of normal-appearing prostatic tissue from the right anterior aspect are procured by and for The prostate is glued back together and submitted permanent sectioning. Also received, yet entirely procured for research lab, labeled "prostate biopsies" are multiple tan threadlike tissue cores. The specimen is received in matching the above description. A whole mount is created based on MRI imaging. The seminal vesicles and vas deferens are taken off of the main prostate and the body of the prostate is placed into the mold with serial sections being made. The serial sections from the apex to the base are placed into whole mount white cassettes labeled . The blue-colored right vas deferens and seminal vesicles are placed into white cassettes 6G-6I and the red-colored left vas deferens and seminal vesicles are placed in white cassette labeled 6L. There is additional tissue that grossly appears to be lymphatic tissue that is placed entirely in white cassette labeled tissue will be completed at a later time point.

Gross Description dictated by and on
Additional Gross Description dictated by

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

[page 5 of 5]
Gender: Male
Admit Protocol

Birth Date:
Admit Protocol:

Admit Protocol:
Age:
Location:

Surgical Pathology

Final Results

Date Report Signed:

W 9/28/13

9/28/13

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By

Do not file in Medical Record

Source: NCI Genomic Data Commons file c57714d1-bf01-4614-9b13-3db0108caf5b (TCGA-VN-A88L.7247904D-2E8C-49B5-8D35-A6CE0D9687DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).